Somatic mutation profile of tumor specimen MMRF_1654_1_BM_CD138pos (aliquot MMRF_1654_1_BM_CD138pos_T1_KBS5U_L05780) from MMRF case MMRF_1654, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 86.7 years (31,668 days).
Specimen MMRF_1654_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 07730516-22cf-4fa6-a0f7-f34e821d4de0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1654_1_PB_WBC (Blood Derived Normal), aliquot MMRF_1654_1_PB_WBC_C3_KBS5U_L05794; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9e868e9c-b0db-4629-b40c-d2af54a2d3cb

The open-access MAF lists 126 somatic variants for this specimen: 53 protein-altering or splice-affecting, 13 silent, 60 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, 3'UTR 39, Silent 13, Intron 10, 5'UTR 4, Frame Shift Del 3, Splice Region 3, 3'Flank 3, Nonsense Mutation 2, Splice Site 2, 5'Flank 2, RNA 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 20/173 reads (12%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ANXA1 | c.36G>A p.W12* | Nonsense Mutation (SNP) | VAF 26/90 reads (29%) | catalogued as rs1279954284; called by muse, mutect2, varscan2
- AQP4 | c.746A>G p.E249G | Missense Mutation (SNP) | VAF 9/148 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.417); catalogued as COSV101270516; called by muse, mutect2
- FGFR2 | c.1361C>T p.T454M | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.241); catalogued as rs148672240; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IGHV3-30 | c.77C>G p.S26C | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as rs767096730; called by muse, varscan2
- IGHV3-30 | c.65A>G p.Q22R | Missense Mutation (SNP) | VAF 28/146 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.02); catalogued as rs1342264245; called by muse, varscan2
- INTS4 | c.1799C>T p.S600F | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.157); catalogued as rs1352066003, COSV71090776; called by mutect2, varscan2
- KRAS | c.190T>A p.Y64N | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55534434, COSV55579983, COSV55703886; called by muse, mutect2, varscan2
- LCE3D | c.217del p.R73Gfs*48 | Frame Shift Del (DEL) | VAF 29/83 reads (35%) | catalogued as rs752603322; called by mutect2, pindel, varscan2
- LSP1 | c.1004G>A p.G335E | Missense Mutation (SNP) | VAF 27/171 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs779033742, COSV61136922; called by muse, mutect2, varscan2
- MAD2L1BP | c.19G>A p.G7R | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT deleterious, low confidence (0); catalogued as rs1260483653; called by muse, mutect2
- MMP16 | c.458G>T p.R153L | Missense Mutation (SNP) | VAF 48/139 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54149112, COSV54151438; called by muse, mutect2, varscan2
- NPAS3 | c.1577G>A p.R526H (on ENST00000356141 / NM_001164749.2; = p.R494H on NM_022123.3) | Missense Mutation (SNP) | VAF 105/232 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.145); catalogued as rs779310871, COSV60851824; called by muse, mutect2, varscan2
- PDCL2 | c.52G>A p.G18S | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs190198366; called by mutect2, varscan2
- PTPRM | c.3860A>G p.N1287S | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs933255444; called by muse, mutect2, varscan2
- RICTOR | c.1552A>G p.I518V | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.092); catalogued as rs781203119; called by muse, mutect2, varscan2
- TRPV1 | c.1782G>A p.A594= | Splice Region (SNP) | VAF 27/73 reads (37%) | catalogued as rs186986460; called by muse, mutect2, varscan2
- ZNF534 | c.1133G>A p.R378Q (on ENST00000332323 / NM_001143939.3; = p.R365Q on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT tolerated (0.56); PolyPhen benign (0.027); catalogued as rs756928217, COSV56516968; called by muse, mutect2, varscan2
- ADGRB3 | c.2080A>G p.N694D | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (1); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- ALX1 | c.335A>G p.E112G | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.007); called by muse, mutect2
- APAF1 | c.1160C>T p.S387F (on ENST00000551964 / NM_181861.2; = p.S376F on NM_001160.3) | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CDKL5 | c.2497-1G>C p.X833_splice | Splice Site (SNP) | VAF 25/34 reads (74%) | called by muse, mutect2, varscan2
- CLTCL1 | c.1478C>A p.A493E | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- COL4A4 | c.2287G>T p.A763S | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- DHX37 | c.1450G>A p.A484T | Missense Mutation (SNP) | VAF 50/132 reads (38%) | SIFT tolerated (0.62); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DIS3 | c.2794-2A>C p.X932_splice | Splice Site (SNP) | VAF 15/25 reads (60%) | called by muse, mutect2, varscan2
- EHD2 | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- EXT2 | c.1284A>C p.E428D (on ENST00000343631; = p.E461D on NM_000401.3) | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM172A | c.725A>C p.D242A | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- FAM214A | c.1120A>G p.I374V | Missense Mutation (SNP) | VAF 44/116 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- FAT4 | c.4132C>A p.L1378M | Missense Mutation (SNP) | VAF 52/143 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FAT4 | c.7559T>A p.L2520Q | Missense Mutation (SNP) | VAF 46/111 reads (41%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- FBN3 | c.32G>T p.G11V | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.207); called by muse, mutect2, varscan2
- FOXQ1 | c.37G>T p.G13W | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.482); called by muse, mutect2, varscan2
- GAB2 | c.1536_1537insAGGG p.V513Rfs*9 (on ENST00000361507 / NM_080491.3; = p.V475Rfs*9 on NM_012296.3) | Frame Shift Ins (INS) | VAF 18/73 reads (25%) | called by mutect2, pindel, varscan2
- GOLIM4 | c.955G>T p.E319* | Nonsense Mutation (SNP) | VAF 70/169 reads (41%) | called by muse, mutect2, varscan2
- HERPUD2 | c.-297-8dup | Splice Region (INS) | VAF 30/83 reads (36%) | called by mutect2, pindel, varscan2
- HS3ST4 | c.497C>A p.T166N | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.603); called by muse, mutect2, varscan2
- IGHV2-70D | c.210del p.R71Afs*14 | Frame Shift Del (DEL) | VAF 24/71 reads (34%) | called by pindel, varscan2
- IGHV4-34 | c.69G>C p.W23C | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- KDELR2 | c.575G>A p.C192Y | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- MICB | c.811del p.R271Gfs*74 | Frame Shift Del (DEL) | VAF 15/64 reads (23%) | called by mutect2, pindel, varscan2
- MIGA2 | c.875C>G p.S292C | Missense Mutation (SNP) | VAF 39/159 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MPPE1 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 4/74 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.262); called by muse, mutect2
- NEBL | c.1658A>T p.E553V | Missense Mutation (SNP) | VAF 25/198 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- PI4K2A | c.1054C>A p.P352T | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PWP1 | c.28G>A p.V10M | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- SMR3B | c.188C>T p.P63L | Missense Mutation (SNP) | VAF 127/341 reads (37%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRADD | c.832C>T p.R278C | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- TTN | c.31362G>A p.V10454= (on ENST00000591111; = p.V9527= on NM_133378.4 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 40/116 reads (34%) | called by muse, mutect2, varscan2
- WDR17 | c.1846A>C p.M616L | Missense Mutation (SNP) | VAF 56/141 reads (40%) | SIFT tolerated (0.64); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZC3H14 | c.1759G>A p.E587K | Missense Mutation (SNP) | VAF 72/139 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- ZSCAN26 | c.187A>C p.T63P | Missense Mutation (SNP) | VAF 41/160 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- AMBRA1 | c.1311G>C p.P437= (on ENST00000458649 / NM_001367468.1; = p.P347= on NM_017749.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 40/124 reads (32%) | catalogued as COSV100093884; called by muse, mutect2, varscan2
- BTN3A2 | c.48C>T p.V16= | Silent (SNP) | VAF 89/371 reads (24%) | called by muse, mutect2, varscan2
- C7orf31 | c.108T>A p.V36= | Silent (SNP) | VAF 30/112 reads (27%) | called by muse, mutect2, varscan2
- CYREN | c.75T>C p.N25= | Silent (SNP) | VAF 53/157 reads (34%) | catalogued as rs1361697456; called by muse, mutect2, varscan2
- DCAF8L2 | c.684C>T p.V228= | Silent (SNP) | VAF 25/38 reads (66%) | catalogued as rs1164637843; called by muse, mutect2, varscan2
- FAP | c.2061A>G p.E687= | Silent (SNP) | VAF 37/123 reads (30%) | called by muse, mutect2, varscan2
- GRM7 | c.1536T>A p.G512= | Silent (SNP) | VAF 43/90 reads (48%) | called by muse, mutect2, varscan2
- IGLL5 | c.138A>G p.Q46= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as rs554492007, COSV73250786; called by muse, mutect2, varscan2
- IGLV4-60 | c.198G>C p.R66= | Silent (SNP) | VAF 51/156 reads (33%) | catalogued as rs141620312; called by muse, mutect2, varscan2
- KIF6 | c.831A>G p.L277= | Silent (SNP) | VAF 35/59 reads (59%) | catalogued as rs1490565964, COSV54684058; called by muse, mutect2, varscan2
- POU4F3 | c.852G>A p.P284= | Silent (SNP) | VAF 20/270 reads (7%) | catalogued as rs763665759, COSV57942539; called by muse, mutect2
- RAB11FIP3 | c.780C>T p.Y260= | Silent (SNP) | VAF 19/42 reads (45%) | catalogued as rs758228777; called by muse, mutect2, varscan2
- SSC5D | c.1236T>C p.P412= | Silent (SNP) | VAF 9/45 reads (20%) | called by muse, mutect2, varscan2
- ACBD3 | c.*1597G>T | 3'UTR (SNP) | VAF 6/81 reads (7%) | catalogued as rs1448309403; called by muse, mutect2
- AP3S1 | c.*55T>G | 3'UTR (SNP) | VAF 42/255 reads (16%) | called by muse, mutect2, varscan2
- ARHGAP29 | c.*301G>A | 3'UTR (SNP) | VAF 23/80 reads (29%) | called by muse, mutect2, varscan2
- ARL14EP | c.-63-2741T>G | Intron (SNP) | VAF 23/48 reads (48%) | called by muse, mutect2, varscan2
- ASAH2 | c.*2442del | 3'UTR (DEL) | VAF 31/94 reads (33%) | called by mutect2, pindel*, varscan2
- BMP3 | c.*2547T>C | 3'UTR (SNP) | VAF 15/46 reads (33%) | called by muse, mutect2, varscan2
- BX537318.2 | n.548C>A | RNA (SNP) | VAF 8/100 reads (8%) | called by muse, mutect2
- CACNA1E | c.*8776A>C | 3'UTR (SNP) | VAF 6/86 reads (7%) | called by muse, mutect2
- CAMK4 | c.*8536G>A | 3'UTR (SNP) | VAF 21/87 reads (24%) | called by muse, mutect2, varscan2
- CASS4 | c.-132G>A | 5'UTR (SNP) | VAF 9/54 reads (17%) | called by muse, mutect2, varscan2
- CCNT2 | c.*3649G>T | 3'UTR (SNP) | VAF 27/68 reads (40%) | called by muse, mutect2, varscan2
- CKAP4 | c.*415T>C | 3'UTR (SNP) | VAF 24/58 reads (41%) | called by muse, mutect2, varscan2
- CSNK1G3 | chr5:123616195 A>G | 3'Flank (SNP) | VAF 6/86 reads (7%) | called by muse, mutect2
- DDN | c.*89T>A | 3'UTR (SNP) | VAF 66/180 reads (37%) | called by muse, mutect2, varscan2
- DIO3 | chr14:101558449 G>A | 5'Flank (SNP) | VAF 42/71 reads (59%) | catalogued as rs528754907; called by muse, mutect2, varscan2
- DNAAF3 | c.481-17C>T | Intron (SNP) | VAF 8/25 reads (32%) | called by muse, mutect2, varscan2
- ERGIC1 | c.*1709_*1710insTA | 3'UTR (INS) | VAF 10/35 reads (29%) | called by mutect2, varscan2
- ERVFRD-1 | c.-47del | 5'UTR (DEL) | VAF 29/120 reads (24%) | called by mutect2, pindel, varscan2
- EXOC8 | c.*572A>G | 3'UTR (SNP) | VAF 15/52 reads (29%) | called by muse, mutect2, varscan2
- FREM2 | c.*2669C>T | 3'UTR (SNP) | VAF 21/39 reads (54%) | called by muse, mutect2, varscan2
- FUT2 | c.*22C>T | 3'UTR (SNP) | VAF 26/130 reads (20%) | called by muse, mutect2
- GALNT9 | c.419+8822G>A | Intron (SNP) | VAF 25/77 reads (32%) | catalogued as rs938775211; called by muse, mutect2, varscan2
- GFAP | chr17:44905468 G>T | 3'Flank (SNP) | VAF 5/14 reads (36%) | called by muse, mutect2, varscan2
- GRHPR | c.*74G>C | 3'UTR (SNP) | VAF 15/69 reads (22%) | called by muse, mutect2, varscan2
- HMSD | c.*125C>G | 3'UTR (SNP) | VAF 47/158 reads (30%) | called by muse, mutect2, varscan2
- IFNA6 | c.*302A>G | 3'UTR (SNP) | VAF 7/34 reads (21%) | called by muse, mutect2, varscan2
- IGLL5 | c.-56C>T | 5'UTR (SNP) | VAF 19/65 reads (29%) | called by muse, mutect2, varscan2
- LIMCH1 | c.*2335G>T | 3'UTR (SNP) | VAF 23/72 reads (32%) | called by muse, mutect2, varscan2
- LMO2 | c.42-58C>A | Intron (SNP) | VAF 61/163 reads (37%) | called by muse, mutect2, varscan2
- LONRF2 | c.*6209G>A | 3'UTR (SNP) | VAF 37/88 reads (42%) | called by muse, mutect2, varscan2
- LTB | c.163-30A>G | Intron (SNP) | VAF 80/357 reads (22%) | catalogued as rs4647184, COSV53002619; called by muse, mutect2, varscan2
- LUZP2 | c.*931G>A | 3'UTR (SNP) | VAF 30/80 reads (38%) | called by muse, mutect2, varscan2
- LYPLA2P2 | n.463C>T | RNA (SNP) | VAF 10/132 reads (8%) | catalogued as rs11880699; called by muse, mutect2
- MDGA1 | c.1609+51C>A | Intron (SNP) | VAF 24/73 reads (33%) | called by muse, mutect2, varscan2
- MYH10 | c.*1005T>C | 3'UTR (SNP) | VAF 34/70 reads (49%) | catalogued as rs886600083; called by muse, mutect2, varscan2
- NOS1 | c.*556A>C | 3'UTR (SNP) | VAF 12/43 reads (28%) | called by muse, mutect2, varscan2
- NOVA1 | c.*439C>A | 3'UTR (SNP) | VAF 12/53 reads (23%) | called by muse, mutect2, varscan2
- NPTX2 | c.*826C>A | 3'UTR (SNP) | VAF 9/39 reads (23%) | called by muse, mutect2, varscan2
- NXPH1 | c.*1019A>T | 3'UTR (SNP) | VAF 41/88 reads (47%) | called by muse, mutect2, varscan2
- PDXDC1 | chr16:14974938 C>T | 5'Flank (SNP) | VAF 16/115 reads (14%) | catalogued as rs1404305218; called by muse, mutect2, varscan2
- PLCB4 | c.*1706C>A | 3'UTR (SNP) | VAF 10/37 reads (27%) | called by muse, mutect2, varscan2
- PLEKHA1 | c.*177A>T | 3'UTR (SNP) | VAF 15/49 reads (31%) | called by muse, mutect2, varscan2
- PLXNA4 | c.*4036C>A | 3'UTR (SNP) | VAF 4/38 reads (11%) | called by muse, varscan2
- PREX2 | c.*3503T>G | 3'UTR (SNP) | VAF 24/52 reads (46%) | called by muse, mutect2
- PTPN1 | c.*1853C>A | 3'UTR (SNP) | VAF 9/20 reads (45%) | called by muse, mutect2, varscan2
- RAB35 | c.53-150C>T | Intron (SNP) | VAF 38/125 reads (30%) | catalogued as rs748579026; called by muse, mutect2, varscan2
- RCE1 | c.185+27C>T | Intron (SNP) | VAF 15/54 reads (28%) | called by muse, mutect2, varscan2
- SCIN | c.*597T>A | 3'UTR (SNP) | VAF 27/87 reads (31%) | called by muse, mutect2, varscan2
- SLC22A4 | c.*46A>C | 3'UTR (SNP) | VAF 85/317 reads (27%) | called by muse, mutect2, varscan2
- SRSF10 | c.*5845A>C | 3'UTR (SNP) | VAF 25/59 reads (42%) | called by muse, mutect2, varscan2
- STPG2 | c.*3067C>A | 3'UTR (SNP) | VAF 16/52 reads (31%) | called by muse, mutect2, varscan2
- TADA2B | c.*69G>A | 3'UTR (SNP) | VAF 74/189 reads (39%) | called by muse, mutect2, varscan2
- TAL1 | c.*3102G>A | 3'UTR (SNP) | VAF 22/82 reads (27%) | called by muse, mutect2, varscan2
- TREML2 | c.*1574_*1575insGACA | 3'UTR (INS) | VAF 3/27 reads (11%) | called by pindel, varscan2*
- UST | c.*2790A>G | 3'UTR (SNP) | VAF 27/91 reads (30%) | called by muse, mutect2, varscan2
- WDR19 | c.1479+384A>G | Intron (SNP) | VAF 37/123 reads (30%) | catalogued as rs1287844072; called by muse, mutect2, varscan2
- YWHAB | c.*53A>G | 3'UTR (SNP) | VAF 43/126 reads (34%) | catalogued as rs1451838517; called by muse, mutect2, varscan2
- ZBTB11 | c.-159C>T | 5'UTR (SNP) | VAF 45/126 reads (36%) | called by muse, mutect2, varscan2
- ZFYVE28 | c.701+5288G>A | Intron (SNP) | VAF 11/33 reads (33%) | catalogued as rs554454803; called by muse, mutect2, varscan2
- ZNF566 | chr19:36447398 G>A | 3'Flank (SNP) | VAF 23/74 reads (31%) | catalogued as rs529205519; called by muse, mutect2, varscan2
